Surgical pathology report (de-identified scan), TCGA case TCGA-UT-A88C, project TCGA-MESO (Mesothelioma), tissue source site Asbestos Diseases Research Institute, specimen TCGA-UT-A88C-01B (Primary Tumor).

HISTOPATHOLOGY REPORT :

CLINICAL NOTES:

Probable mesothelioma on needle biopsy R chest wall.

MACROSCOPIC:

'Parietal pleura'. The specimen consists of six strips of grey soft tissue ranging between 5mm and 100mm in maximal dimension. There is a 5mm separate fatty nodule. No definite tumour is identified. The tissue is divided and all embedded. (Blocks A & B)

MICROSCOPIC:

The previous pathology (FNA and core biopsy, review,

noted, however, is unavailable currently for

This specimen consists of portions of pleura including pleural adipose tissue and skeletal muscle. It contains an infiltrate of large, epithelioid malignant cells arranged in cohesive aggregates with a pseudoacinar, tubular and micropapillary patterns. The cells have large irregular nuclei with prominent nucleoli and a variable amount of eosinophilic to clear cytoplasm. There is a background fibrous stroma. The malignant cells infiltrate into and amongst adipose tissue. No necrosis is seen. No sarcomatoid areas are identified. Immunohistochemistry shows strong positive staining of the malignant cells for calretinin 34BE12, HBME1 and CK7, and patchy staining for CK5/6. There is no significant staining for CEA, MOC31, CK20 and TTF1.

The histologic features and immunohistochemical profile are compatible with the diagnosis of malignant mesothelioma of epithelioid type.

DIAGNOSIS:

RIGHT PARIETAL PLEURA - MALIGNANT MESOTHELIOMA, EPITHELIOID SUBTYPE

Reported by

ICD-0-3

Mesothelioma, epithelioid, malignant 9052/3

Site C38.4
Pleura NOS C38.4

path

Parietal pleura C38.4

9/10/30/13

IHPAA Discrepancy		

Surge Use

☐ Norm

☐ No-Actio File

☐ Contac Patient

☐ See Patient

☐ See File

☐ Continue Treatment

Signed

Date

Source: NCI Genomic Data Commons file 553124cc-c52e-47a5-92f7-0ac7ff98c21d (TCGA-UT-A88C.1ED5E6B0-FEBE-447E-B5A1-3771DAEC0513.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).